Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A2LK, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A2LK-01A (Primary Tumor).

ICD-0-3
carcinoma, infiltrating lobular, NOS 8520/3
Site: breast, NOS C50.9 *hw*
8/17/11

Final Diagnosis

Breast, right, wide local excision: Infiltrating lobular carcinoma, Nottingham grade II (of III)[tubules 3/3, nuclei 2/3, mitoses 1/3; Nottingham score 6/9], forming a 5.2 x 3.0 x 2.6 cm mass. Lobular carcinoma in situ is present and represents less than 5% of the overall tumor volume. Angiolymphatic invasion is present. The non-neoplastic breast parenchyma show nonproliferative fibrocystic changes. Calcifications present in benign ducts and acini. Biopsy site changes present. The inferior and medial margins are positive for invasive carcinoma.

Breast, right, total mastectomy: Infiltrating lobular carcinoma, Nottingham grade II (of III), involving the medial aspect of the biopsy cavity. Two additional nodules of Nottingham grade II (of III) invasive lobular carcinoma are identified in the lower outer quadrant (0.7 x 0.6 x 0.5 cm, located 1.4 cm from the deep margin; and 0.5 x 0.4 x 0.4 cm, located 1.2 cm from the deep margin). Lobular carcinoma in situ is present and represents less than 5% of the overall tumor volume. Angiolymphatic invasion is present. The non-neoplastic breast parenchyma shows proliferative fibrocystic changes. Biopsy site changes present. The tumor does not involve the nipple, overlying skin, or underlying chest wall. All surgical resection margins, including the deep margin, are negative for tumor (residual tumor in the biopsy cavity is located 2.2 cm from the deep margin).

Lymph nodes, right axillary, dissection: Multiple (5 of 18) right axillary lymph nodes are positive for metastatic carcinoma [AJCC pN2]. The largest is represented by a matted mass of lymph nodes and measures 4.2 x 2.6 x 2.4 cm. Extranodal extension is present.

Comment: Final (mastectomy) surgical margins are widely free of involvement.

HIVAA Discrepancy		

Source: NCI Genomic Data Commons file f4c63d6e-d1b3-4598-820a-57c6b16d70ff (TCGA-AR-A2LK.73FFBADB-37C0-4F17-8C95-F8DC94EF1AD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).